Somatic mutation profile of tumor specimen TCGA-FS-A4F0-06A (aliquot TCGA-FS-A4F0-06A-11D-A24R-08) from TCGA case TCGA-FS-A4F0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.7 years (25,446 days).
Specimen TCGA-FS-A4F0-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8ef17e5-3f78-4f32-bf96-93688a761521.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4F0-10A (Blood Derived Normal), aliquot TCGA-FS-A4F0-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4c2e627-5ebe-458a-b173-0d6dad1fd208

The open-access MAF lists 655 somatic variants for this specimen: 437 protein-altering or splice-affecting, 204 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 392, Silent 204, Nonsense Mutation 26, Splice Site 9, Intron 9, Splice Region 5, Frame Shift Del 3, 3'UTR 3, RNA 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPHS1 | c.3312-1G>A p.X1104_splice | Splice Site (SNP) | VAF 147/314 reads (47%) | catalogued as rs786204729, CS097056, COSV62289456; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PEX14 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 74/166 reads (45%) | catalogued as rs61752116, CM041420, COSV63063494; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1530G>T p.Q510H | Missense Mutation (SNP) | VAF 312/327 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM117756, COSV61005626, COSV61006865; called by muse, mutect2, varscan2
- RPGRIP1 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs565837539, CM1312225, COSV52845281; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 163/360 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.505); catalogued as COSV52934183; called by muse, mutect2, varscan2
- ABCA13 | c.10627G>A p.E3543K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV71292558; called by muse, mutect2, varscan2
- ABCC12 | c.2124G>A p.K708= | Splice Region (SNP) | VAF 57/126 reads (45%) | catalogued as COSV60914283; called by muse, mutect2, varscan2
- ABHD1 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV53208182; called by muse, mutect2, varscan2
- ACAN | c.4876C>T p.P1626S | Missense Mutation (SNP) | VAF 141/305 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs767764933, COSV61356259; called by muse, mutect2, varscan2
- ACP7 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs144395661, COSV58700117; called by muse, mutect2, varscan2
- ACTC1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 155/319 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs543030688, CM0910610, COSV51758568; called by muse, mutect2, varscan2
- ADAM28 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV56105281; called by muse, mutect2, varscan2
- ADAMTS13 | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT tolerated (0.65); PolyPhen benign (0.02); catalogued as COSV63023105; called by muse, mutect2, varscan2
- ADAMTS7 | c.1340G>A p.C447Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1463155710, COSV66309376; called by muse, mutect2, varscan2
- ADD3 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53325837; called by muse, mutect2, varscan2
- ADGRA3 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99293667; called by muse, mutect2, varscan2
- ADGRA3 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99293675; called by muse, mutect2, varscan2
- AKAP6 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV55232868; called by muse, mutect2, varscan2
- AKAP9 | c.2972C>T p.S991L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781772492, COSV62357713; called by muse, mutect2, varscan2
- AKR1C3 | c.873G>C p.E291D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs782061306, COSV65911175; called by muse, mutect2, varscan2
- ALDH1B1 | c.1491T>A p.D497E | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (0.12); PolyPhen benign (0.299); catalogued as COSV66620623; called by muse, mutect2, varscan2
- ALOX15 | c.1366A>G p.K456E | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV53400575; called by muse, mutect2, varscan2
- AMER3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs775305041, COSV100366877, COSV58465397; called by muse, mutect2, varscan2
- AMPD1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587779370, COSV62417012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD30A | c.1018C>T p.Q340* (on ENST00000611781; = p.Q284* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 46/101 reads (46%) | catalogued as COSV64610873; called by muse, mutect2, varscan2
- ANO3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56808175; called by muse, mutect2, varscan2
- APOB | c.4951G>A p.G1651R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs748424949, COSV51951719; called by muse, mutect2, varscan2
- ARID4A | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.29); catalogued as rs756433888, COSV62166604; called by muse, mutect2, varscan2
- ARID4B | c.3664+1G>T p.X1222_splice | Splice Site (SNP) | VAF 37/84 reads (44%) | catalogued as COSV51611073; called by muse, mutect2, varscan2
- ARL14EP | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1488921270, COSV99956010; called by muse, mutect2, varscan2
- ARMH3 | c.1799T>A p.F600Y | Missense Mutation (SNP) | VAF 158/355 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV64238107; called by muse, mutect2, varscan2
- ARPP21 | c.977A>T p.K326M | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99492888; called by muse, mutect2, varscan2
- ATG12 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57243746; called by muse, mutect2, varscan2
- ATP13A2 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.142); catalogued as rs1342110935, COSV58703623; called by muse, mutect2, varscan2
- ATR | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs764261046, COSV63392196; called by muse, mutect2, varscan2
- BBS9 | c.1883G>A p.G628E (on ENST00000242067 / NM_001348036.1; = p.G588E on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as rs748849364, COSV54186848; called by muse, mutect2, varscan2
- BBX | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.646); catalogued as COSV57894511; called by muse, mutect2, varscan2
- BDP1 | c.7441C>T p.P2481S | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62431448, COSV62434626; called by muse, mutect2, varscan2
- BFAR | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99902391; called by muse, mutect2, varscan2
- BOC | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV56357850; called by muse, mutect2, varscan2
- BTAF1 | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV56437719; called by muse, mutect2, varscan2
- C10orf71 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs775295000, COSV100110267, COSV60513078; called by muse, mutect2, varscan2
- C10orf71 | c.890T>A p.V297D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV100110536; called by muse, mutect2, varscan2
- C14orf180 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 114/259 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59557282, COSV59557848; called by muse, mutect2, varscan2
- C16orf78 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV54555053; called by muse, mutect2, varscan2
- C3orf38 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59628987; called by muse, mutect2, varscan2
- C5orf34 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV60932003; called by muse, mutect2, varscan2
- C6 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV54704946; called by muse, mutect2, varscan2
- C6orf118 | c.545T>C p.L182S | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV57819038; called by muse, mutect2, varscan2
- C6orf58 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as COSV61667048; called by muse, mutect2, varscan2
- CACNA1H | c.4558G>A p.D1520N | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs555853603, COSV100673700, COSV61993062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.1724C>T p.S575F (on ENST00000324631 / NM_201596.3; = p.S520F on NM_000724.4) | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.303); catalogued as COSV56646342; called by muse, mutect2, varscan2
- CAMTA1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57926039; called by muse, mutect2, varscan2
- CARMIL3 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV57728298; called by muse, mutect2, varscan2
- CASQ1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.401); catalogued as COSV63624539; called by muse, mutect2, varscan2
- CCDC170 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs267600858, COSV53337046; called by muse, mutect2, varscan2
- CCDC181 | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV63155765, COSV63156852, COSV63158102; called by muse, mutect2, varscan2
- CCDC27 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767384697, COSV53903557; called by muse, mutect2, varscan2
- CCDC33 | c.546G>A p.E182= | Splice Region (SNP) | VAF 37/65 reads (57%) | catalogued as COSV58357869; called by muse, varscan2
- CCDC33 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58357887; called by muse, mutect2, varscan2
- CCDC96 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.258); catalogued as rs763116363, COSV59509491; called by muse, mutect2, varscan2
- CCNK | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV66275810; called by muse, mutect2, varscan2
- CD101 | c.2072C>T p.S691F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs749784429, COSV56721070; called by muse, mutect2, varscan2
- CD180 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56519792; called by muse, mutect2, varscan2
- CD33 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as COSV51800256; called by muse, mutect2, varscan2
- CDC27 | c.27G>A p.Q9= | Splice Region (SNP) | VAF 33/72 reads (46%) | catalogued as COSV50673076; called by muse, mutect2, varscan2
- CDH20 | c.1588T>A p.Y530N | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); catalogued as COSV53006188, COSV53017856; called by muse, mutect2, varscan2
- CEACAM18 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 132/295 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs770488716, COSV101140608; called by muse, varscan2
- CEACAM18 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 130/290 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101140610; called by muse, varscan2
- CEACAM20 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.049); catalogued as COSV57600748; called by muse, mutect2, varscan2
- CFAP94 | c.653A>G p.N218S (on ENST00000320267 / NM_001352064.2; = p.N224S on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57236652; called by muse, mutect2, varscan2
- CFH | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as rs771112278, COSV62778409; called by muse, mutect2, varscan2
- CFHR3 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66403259; called by muse, mutect2, varscan2
- CHRM3 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55103986; called by muse, mutect2, varscan2
- CHRNA1 | c.189+1G>A p.X63_splice | Splice Site (SNP) | VAF 98/251 reads (39%) | catalogued as rs1358667538, COSV53685217; called by muse, mutect2, varscan2
- CHRNA2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV53559692; called by muse, mutect2, varscan2
- CMBL | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV99687200; called by muse, mutect2, varscan2
- CNTN3 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747484787, COSV55161998; called by muse, mutect2, varscan2
- COL19A1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1292226287, COSV59587665; called by muse, mutect2, varscan2
- COL21A1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as COSV55179312; called by muse, mutect2, varscan2
- COL4A6 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57874627; called by muse, mutect2, varscan2
- COL5A3 | c.2038G>A p.G680S | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53405895; called by muse, mutect2, varscan2
- COL6A5 | c.6359G>A p.R2120H (on ENST00000312481; = p.R2116H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs146634521; called by muse, mutect2, varscan2
- CREB3L2 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57800019; called by muse, mutect2, varscan2
- CSNK1E | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 114/126 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63292132; called by muse, mutect2, varscan2
- CSRP1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100384548; called by muse, mutect2, varscan2
- CTNNA3 | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV65551521, COSV65555140, COSV65598974; called by muse, mutect2, varscan2
- CTPS2 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100826993; called by muse, mutect2, varscan2
- CYRIA | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.26); catalogued as COSV62867167; called by muse, mutect2
- DAG1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV58187142; called by muse, mutect2, varscan2
- DAZL | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51714465; called by muse, mutect2, varscan2
- DCAF4L2 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60482308; called by muse, mutect2, varscan2
- DDX42 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 121/259 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as COSV63791366; called by muse, mutect2, varscan2
- DENND2A | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs780892963, COSV52055867; called by muse, mutect2, varscan2
- DENND2A | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99326721; called by muse, mutect2, varscan2
- DEPTOR | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV53821947; called by muse, mutect2, varscan2
- DGKI | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55935459; called by muse, mutect2, varscan2
- DHODH | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV54663707; called by muse, mutect2
- DHTKD1 | c.689T>C p.L230S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53806899; called by muse, mutect2, varscan2
- DNAH12 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60856330; called by muse, mutect2
- DNAH2 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs140826418; called by muse, mutect2, varscan2
- DNAH3 | c.9346G>A p.E3116K | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54550653; called by muse, mutect2, varscan2
- DNAH5 | c.5374C>T p.L1792F | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs770557925, COSV54251142; called by muse, mutect2, varscan2
- DNAH6 | c.2332A>G p.T778A | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV52867956; called by muse, mutect2, varscan2
- DNAH7 | c.6677G>A p.R2226K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1338728754, COSV56785353; called by muse, mutect2, varscan2
- DNAH8 | c.11357G>A p.G3786E | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59479540; called by muse, mutect2, varscan2
- DNAI1 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54284622; called by muse, mutect2, varscan2
- DNAJB7 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV53421682; called by muse, mutect2, varscan2
- DPP9 | c.510C>A p.F170L (on ENST00000598800; = p.F199L on NM_139159.5) | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.771); catalogued as COSV53589418, COSV53594244; called by muse, mutect2, varscan2
- DQX1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.63); catalogued as rs1260801972, COSV101098866, COSV66353656; called by muse, mutect2, varscan2
- DSC1 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV57151350; called by muse, mutect2, varscan2
- DSCAM | c.329A>T p.K110I | Missense Mutation (SNP) | VAF 81/154 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV68653924; called by muse, mutect2, varscan2
- E2F8 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51462683; called by muse, mutect2, varscan2
- EAF2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV56546093; called by muse, mutect2, varscan2
- EBF3 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV62481672; called by muse, mutect2, varscan2
- ECE1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV51670410; called by muse, mutect2, varscan2
- EFEMP2 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV57261496; called by muse, mutect2, varscan2
- EMILIN3 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60038716; called by muse, mutect2, varscan2
- ENPEP | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54450318, COSV54457280; called by muse, mutect2, varscan2
- EPHA1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 155/340 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as rs781509885, COSV51970381, COSV51976424; called by muse, mutect2, varscan2
- EPHB4 | c.2665C>T p.R889W | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs762016655, COSV62268494, COSV62271028; called by muse, mutect2, varscan2
- EPPK1 | c.4384T>C p.F1462L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV73261034, COSV73262364; called by muse, mutect2, varscan2
- EPX | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56596041; called by muse, mutect2, varscan2
- ETNPPL | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56597504; called by muse, mutect2, varscan2
- FAM120C | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV60262455; called by muse, mutect2, varscan2
- FAM172A | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV67941918; called by muse, mutect2, varscan2
- FAM184A | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs572508377, COSV58858711; called by muse, mutect2
- FAM71A | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 116/210 reads (55%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.678); catalogued as COSV54237229; called by muse, mutect2, varscan2
- FAM89B | c.494C>G p.P165R (on ENST00000530349 / NM_001098785.2; = p.P152R on NM_152832.3) | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV57079731, COSV57080195; called by muse, mutect2, varscan2
- FASN | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs200575117; called by muse, mutect2, varscan2
- FASN | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100148187; called by muse, mutect2, varscan2
- FBN2 | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1327195986, COSV52544567; called by muse, mutect2, varscan2
- FBXL14 | c.314A>T p.D105V | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59337554; called by muse, mutect2, varscan2
- FCRL5 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1292646691, COSV62520026; called by muse, mutect2, varscan2
- FLG | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 333/1086 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV64239213, COSV64248869; called by muse, mutect2, varscan2
- FREM1 | c.5288T>A p.I1763N | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66529992, COSV66532138; called by muse, mutect2, varscan2
- FRY | c.7576G>T p.E2526* | Nonsense Mutation (SNP) | VAF 30/99 reads (30%) | catalogued as COSV66579967; called by muse, mutect2, varscan2
- FYB2 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.204); catalogued as COSV58588420; called by muse, mutect2, varscan2
- FZD3 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 62/139 reads (45%) | catalogued as rs762771274, COSV53537792; called by muse, mutect2, varscan2
- GALNT18 | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57157708; called by muse, mutect2, varscan2
- GHSR | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53840859; called by muse, mutect2, varscan2
- GINS2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 105/221 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53681165; called by muse, mutect2, varscan2
- GLP2R | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs1283490517, COSV52329469; called by muse, mutect2, varscan2
- GORASP2 | c.911-1G>A p.X304_splice | Splice Site (SNP) | VAF 60/121 reads (50%) | catalogued as COSV52201191, COSV52203879; called by muse, mutect2, varscan2
- GPATCH1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50126317; called by muse, mutect2, varscan2
- GPR65 | c.85A>C p.I29L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV50864257; called by muse, mutect2, varscan2
- GPRC6A | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV59953171; called by muse, mutect2, varscan2
- GRIK4 | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs780591152, COSV70807124; called by muse, mutect2, varscan2
- GRIN2A | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58056446; called by muse, mutect2, varscan2
- HACE1 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as COSV53507884, COSV99493132; called by muse, mutect2, varscan2
- HADH | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748945961, COSV58849660, COSV58850179; called by muse, mutect2, varscan2
- HDAC9 | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV67784937; called by muse, mutect2, varscan2
- HEPHL1 | c.2479T>A p.F827I | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59896340; called by muse, mutect2, varscan2
- HERC1 | c.9655C>T p.R3219* | Nonsense Mutation (SNP) | VAF 47/97 reads (48%) | catalogued as COSV101496802; called by muse, mutect2, varscan2
- HFM1 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54022066; called by muse, mutect2, varscan2
- HHIP | c.1864A>T p.K622* | Nonsense Mutation (SNP) | VAF 48/109 reads (44%) | catalogued as COSV56844054; called by muse, mutect2, varscan2
- HMGCS2 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65569217; called by muse, mutect2, varscan2
- HMSD | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748662951, COSV68817092; called by muse, mutect2, varscan2
- HNRNPCL1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs760188448, COSV58614997; called by muse, mutect2, varscan2
- HRNR | c.5390G>A p.G1797E | Missense Mutation (SNP) | VAF 92/3446 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.294); catalogued as rs1210504824; called by muse, mutect2
- HYDIN | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV101143176; called by muse, mutect2, varscan2
- IARS2 | c.1820G>C p.W607S | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56963944; called by muse, mutect2, varscan2
- IL12A | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as COSV59760169; called by muse, mutect2, varscan2
- IL18R1 | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52127278; called by muse, mutect2
- IL22RA1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759880038, COSV54630385; called by muse, mutect2, varscan2
- IL31RA | c.794G>A p.W265* | Nonsense Mutation (SNP) | VAF 67/137 reads (49%) | catalogued as COSV51685076; called by muse, mutect2, varscan2
- ILVBL | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99655074; called by muse, mutect2, varscan2
- INA | c.1396A>G p.I466V | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63976553; called by muse, mutect2, varscan2
- INPP4A | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs774761280, COSV50798464; called by muse, mutect2, varscan2
- IRX1 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV57362334; called by muse, mutect2, varscan2
- ITIH2 | c.1073G>A p.W358* | Nonsense Mutation (SNP) | VAF 39/80 reads (49%) | catalogued as rs771294645, COSV64433142, COSV64435191; called by muse, mutect2, varscan2
- ITPR3 | c.6623C>T p.S2208F | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65414753; called by muse, mutect2, varscan2
- JAKMIP3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV53829138; called by muse, mutect2, varscan2
- KCNB1 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 75/181 reads (41%) | catalogued as COSV65570770; called by muse, mutect2, varscan2
- KCNJ15 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV60811977; called by muse, mutect2, varscan2
- KCNQ2 | c.1669G>A p.E557K (on ENST00000359125 / NM_172107.4; = p.E529K on NM_004518.6) | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60553970; called by muse, mutect2, varscan2
- KIAA0753 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV63818934; called by muse, mutect2, varscan2
- KIAA1109 | c.13112C>T p.S4371F | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373071885, COSV52691654; called by muse, mutect2, varscan2
- KIAA1217 | c.4732C>T p.P1578S | Missense Mutation (SNP) | VAF 113/245 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56823607; called by muse, mutect2, varscan2
- KMT2C | c.13081A>T p.S4361C | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV51500962; called by muse, varscan2
- KMT2C | c.13019G>A p.G4340D | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.154); catalogued as COSV51500978; called by muse, varscan2
- KPNA4 | c.331A>T p.I111L | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62076992; called by muse, mutect2, varscan2
- KRT31 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52438553, COSV99290256; called by muse, mutect2, varscan2
- LAMA2 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV70354889; called by muse, mutect2, varscan2
- LAMA2 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1485209355, COSV70354891; called by muse, mutect2, varscan2
- LAMA4 | c.4322C>T p.P1441L (on ENST00000230538 / NM_001105206.3; = p.P1434L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs782186408, COSV57904641; called by muse, mutect2, varscan2
- LIPA | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV51080669; called by muse, mutect2, varscan2
- LMF1 | c.1153A>C p.N385H | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51902430; called by muse, mutect2, varscan2
- LONP2 | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.73); PolyPhen benign (0.109); catalogued as rs760015397, COSV53521223, COSV53526141; called by muse, mutect2, varscan2
- LPAR1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT tolerated (0.46); PolyPhen benign (0.088); catalogued as rs935949106, COSV62691406; called by muse, mutect2, varscan2
- LPIN2 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV55244139; called by muse, mutect2, varscan2
- LRRC31 | c.541A>C p.S181R | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV52982935; called by muse, mutect2, varscan2
- MAGEA11 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 184/198 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs782802430, COSV60758698; called by muse, mutect2, varscan2
- MAGEB6 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 183/202 reads (91%) | SIFT tolerated (0.14); PolyPhen benign (0.215); catalogued as COSV66872552, COSV66873039; called by muse, mutect2, varscan2
- MAGI2 | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV62697748; called by muse, mutect2, varscan2
- MAP3K19 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV59642169; called by muse, mutect2, varscan2
- MARCHF7 | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.395); catalogued as rs1560016163, COSV52031343; called by muse, mutect2, varscan2
- MARK4 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 91/166 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); catalogued as rs35070611; called by muse, mutect2, varscan2
- MASP2 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as COSV68897523; called by muse, mutect2, varscan2
- MC5R | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 148/315 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV61254095; called by muse, mutect2, varscan2
- MCHR2 | c.435A>C p.R145S | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56008657, COSV99911516; called by muse, mutect2, varscan2
- MCTP2 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59150167; called by muse, mutect2, varscan2
- MECOM | c.1643G>A p.G548D (on ENST00000468789 / NM_001105078.4; = p.G736D on NM_004991.4) | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs558610353, COSV52974335; called by muse, mutect2, varscan2
- METTL7B | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769045151, COSV57697604; called by muse, mutect2, varscan2
- MGAM | c.2587G>A p.D863N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as rs374784553; called by muse, mutect2, varscan2
- MIDN | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs540283060, COSV56296924; called by muse, mutect2, varscan2
- MINDY3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs776784319, COSV53219143; called by muse, mutect2, varscan2
- MLLT3 | c.1576-1G>A p.X526_splice | Splice Site (SNP) | VAF 24/27 reads (89%) | catalogued as COSV100581454; called by muse, mutect2, varscan2
- MMP1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV59510428; called by muse, mutect2, varscan2
- MPV17L2 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV55853847; called by muse, mutect2, varscan2
- MS4A10 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 88/181 reads (49%) | catalogued as rs751639552, COSV57633903; called by muse, mutect2, varscan2
- MYH11 | c.2776G>T p.E926* | Nonsense Mutation (SNP) | VAF 127/304 reads (42%) | catalogued as COSV55569258; called by muse, mutect2, varscan2
- MYH14 | c.5390C>T p.S1797L | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.792); catalogued as COSV51825689, COSV51830841; called by muse, mutect2, varscan2
- MYH3 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs750125413, COSV56862033; called by muse, mutect2, varscan2
- MYLK | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 79/169 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60608109; called by muse, mutect2, varscan2
- MYO7B | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs757581563, COSV67346716; called by muse, mutect2, varscan2
- MYO9A | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs781327003, COSV61850409; called by muse, mutect2, varscan2
- MYOF | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV63710497; called by muse, mutect2, varscan2
- MYOZ1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775615695, COSV63772612; called by muse, mutect2, varscan2
- NAALADL2 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs1408575182, COSV71986909; called by muse, mutect2, varscan2
- NCOA3 | c.2743C>T p.P915S | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV59073329; called by muse, mutect2, varscan2
- NCR1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV52556814; called by muse, mutect2, varscan2
- NCR2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs780559376, COSV66101315; called by muse, mutect2, varscan2
- NEK5 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 119/301 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs750899823, COSV62879023; called by muse, mutect2, varscan2
- NEXMIF | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 52/57 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs749042303, COSV50057278; called by muse, mutect2, varscan2
- NEXMIF | c.705T>A p.Y235* | Nonsense Mutation (SNP) | VAF 113/124 reads (91%) | catalogued as COSV50102925; called by muse, mutect2, varscan2
- NLRC5 | c.3022C>T p.H1008Y | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99347987; called by muse, mutect2, varscan2
- NLRP10 | c.1817G>C p.S606T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100149836, COSV60782607; called by muse, mutect2, varscan2
- NME4 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 128/241 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54792352; called by muse, mutect2, varscan2
- NOS1AP | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.015); catalogued as COSV62633682; called by muse, mutect2, varscan2
- NPC1 | c.1820G>C p.R607P | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52583558; called by muse, mutect2, varscan2
- NQO2 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | catalogued as COSV57643622; called by muse, mutect2, varscan2
- NRXN1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs777080356, COSV68046502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSMAF | c.1368T>G p.F456L | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50700584; called by muse, mutect2, varscan2
- NUDT2 | c.114G>A p.W38* | Nonsense Mutation (SNP) | VAF 62/71 reads (87%) | catalogued as COSV60678931; called by muse, mutect2, varscan2
- NUDT7 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.606); catalogued as rs781449552, COSV51747126; called by muse, mutect2, varscan2
- NWD1 | c.2159C>T p.S720L | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60351378; called by muse, mutect2, varscan2
- NYAP2 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.856); catalogued as rs1371116859, COSV99798021; called by muse, mutect2, varscan2
- OR10AG1 | c.728T>A p.F243Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.035); catalogued as COSV56634654; called by muse, varscan2
- OR10J3 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV59955638; called by muse, mutect2, varscan2
- OR10W1 | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV67720854; called by muse, mutect2, varscan2
- OR14K1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99315396; called by muse, mutect2, varscan2
- OR2J2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV65848367, COSV65848461; called by muse, mutect2, varscan2
- OR2L8 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.014); catalogued as COSV61727974; called by muse, mutect2, varscan2
- OR4A5 | c.386A>C p.H129P | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV60524598; called by muse, mutect2, varscan2
- OR4C46 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV100060896, COSV60218974; called by muse, mutect2, varscan2
- OR4C46 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as COSV60221033; called by muse, mutect2, varscan2
- OR51L1 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV58624743, COSV58625749; called by muse, mutect2, varscan2
- OR52I2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57046158; called by muse, varscan2
- OR5AR1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 154/311 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.254); catalogued as COSV57253460, COSV57255300; called by muse, mutect2, varscan2
- OR5I1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56889096; called by muse, mutect2, varscan2
- OR5L2 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 124/250 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs148523172, COSV65723301, COSV65724665; called by muse, mutect2, varscan2
- OR8S1 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); catalogued as COSV100043625; called by muse, mutect2, varscan2
- OR8S1 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.582); catalogued as COSV100043696; called by muse, mutect2, varscan2
- OR9Q1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100110337, COSV59047025; called by muse, mutect2, varscan2
- OSBPL6 | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 36/94 reads (38%) | catalogued as COSV51910659; called by muse, mutect2, varscan2
- OTOGL | c.454G>A p.D152N (on ENST00000547103; = p.D143N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV72007475; called by muse, mutect2, varscan2
- OTOGL | c.6041C>T p.P2014L (on ENST00000547103; = p.P2005L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV54023488; called by muse, mutect2, varscan2
- PCDHA3 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 88/99 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs140331962; called by muse, mutect2, varscan2
- PCGF3 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV62859678; called by muse, mutect2, varscan2
- PCLO | c.12698G>A p.R4233K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1239757423, COSV61665223; called by muse, mutect2, varscan2
- PCLO | c.9287C>T p.P3096L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61665232; called by muse, mutect2, varscan2
- PCLO | c.4796G>A p.G1599E | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.229); catalogued as COSV61632527; called by muse, mutect2, varscan2
- PCNX2 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs556306896, COSV50887714; called by muse, mutect2, varscan2
- PDE3A | c.1269G>A p.K423= | Splice Region (SNP) | VAF 22/66 reads (33%) | catalogued as COSV62982623; called by muse, mutect2, varscan2
- PDE3A | c.2244T>G p.D748E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62982628; called by muse, varscan2
- PDE9A | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368665913; called by muse, mutect2, varscan2
- PEAR1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52775831; called by muse, mutect2, varscan2
- PEG3 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV55647142; called by muse, mutect2, varscan2
- PENK | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as rs367963946; called by muse, mutect2, varscan2
- PER3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs145870917; called by muse, mutect2, varscan2
- PHF7 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59981930; called by muse, mutect2, varscan2
- PHOX2B | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV56931521; called by muse, mutect2, varscan2
- PI4KA | c.2166C>A p.D722E | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV55422714; called by muse, mutect2, varscan2
- PKHD1 | c.4898C>T p.S1633F | Missense Mutation (SNP) | VAF 122/252 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758390540, COSV61894411; called by muse, mutect2, varscan2
- PKN1 | c.2576G>A p.G859E | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52876500; called by muse, mutect2, varscan2
- PLCH1 | c.244C>T p.H82Y (on ENST00000340059 / NM_001130960.2; = p.H94Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV58209948; called by muse, mutect2, varscan2
- PLCL2 | c.584G>A p.R195K (on ENST00000615277 / NM_001144382.2; = p.R69K on NM_015184.5) | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV67625242; called by muse, mutect2, varscan2
- PLIN4 | c.1502G>A p.G501E (on ENST00000301286; = p.G516E on NM_001367868.2) | Missense Mutation (SNP) | VAF 141/282 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV56698562; called by muse, mutect2, varscan2
- PLPP3 | c.764A>G p.D255G | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64840595; called by muse, mutect2, varscan2
- POLQ | c.6692C>T p.P2231L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480849833, COSV51761088, COSV99951721; called by muse, mutect2, varscan2
- POLQ | c.3530C>T p.S1177L | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); catalogued as COSV51761100; called by muse, mutect2, varscan2
- POR | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101203718; called by muse, mutect2, varscan2
- PPP1R9A | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs779336876, COSV56910186; called by muse, mutect2, varscan2
- PPP2R3A | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV53870544; called by muse, mutect2, varscan2
- PPP6R2 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1287619163, COSV99324673; called by muse, mutect2, varscan2
- PRMT1 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV54922149; called by muse, varscan2
- PROSER1 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV61489627, COSV61490105; called by muse, mutect2, varscan2
- PRRG1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 73/76 reads (96%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV66156670; called by muse, mutect2, varscan2
- PSMB6 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567002; called by muse, mutect2, varscan2
- PSMB6 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567003; called by muse, mutect2, varscan2
- PTPRD | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs770180884, COSV61927249, COSV61932779; called by muse, mutect2, varscan2
- PTPRG | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55662263; called by muse, mutect2, varscan2
- PTPRT | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs758531464, COSV61967363; called by muse, mutect2
- PXDNL | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs747795190, COSV62498163; called by muse, mutect2, varscan2
- PYM1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 195/467 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV56813009; called by muse, mutect2, varscan2
- RAD51B | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV66854959; called by muse, mutect2, varscan2
- RAF1 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as COSV52583942; called by muse, mutect2, varscan2
- RAG1 | c.2996C>T p.S999F | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100200623, COSV55024202; called by muse, mutect2, varscan2
- RALGAPA2 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52510732; called by muse, mutect2
- RAP1GAP2 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0.102); catalogued as COSV54588610; called by muse, mutect2, varscan2
- RARG | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 109/210 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58434670; called by muse, mutect2, varscan2
- RNF112 | c.933G>A p.Q311= | Splice Region (SNP) | VAF 60/128 reads (47%) | catalogued as COSV71327118; called by muse, mutect2, varscan2
- RORC | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1330887604, COSV59095582; called by muse, mutect2, varscan2
- RP1 | c.6415G>A p.E2139K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs748387149, COSV55126447; called by muse, mutect2, varscan2
- RRP1B | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1187945415, COSV61480497; called by muse, mutect2, varscan2
- RTL9 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 116/130 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV71826383; called by muse, mutect2, varscan2
- RTN1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV50725112; called by muse, mutect2, varscan2
- RYR2 | c.4621C>T p.P1541S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762729094, COSV63695867; called by muse, mutect2, varscan2
- RYR3 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66808023; called by muse, mutect2, varscan2
- SALL1 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51764452; called by muse, varscan2
- SELP | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781651444, COSV55258362; called by muse, mutect2, varscan2
- SERPING1 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as COSV53544281; called by muse, mutect2, varscan2
- SERPINH1 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1218823155, COSV63998654; called by muse, mutect2, varscan2
- SETD4 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs775158836, COSV59773197, COSV59773933; called by muse, mutect2, varscan2
- SGSM2 | c.1994C>T p.P665L (on ENST00000426855 / NM_001098509.2; = p.P710L on NM_014853.3) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99280414; called by muse, mutect2, varscan2
- SI | c.3082G>A p.D1028N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1425000303, COSV52288023; called by muse, mutect2, varscan2
- SIGLEC5 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55783005, COSV55783837; called by muse, mutect2, varscan2
- SIPA1L1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.575); catalogued as COSV62173538; called by muse, mutect2, varscan2
- SIPA1L2 | c.1912C>A p.L638I | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV53399665; called by muse, mutect2, varscan2
- SLC12A3 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV52638919; called by muse, mutect2, varscan2
- SLC13A3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs866802774, COSV51717794; called by muse, mutect2, varscan2
- SLC1A4 | c.1324A>T p.T442S | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV52235966; called by muse, mutect2, varscan2
- SLC22A14 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 110/210 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs144855969; called by muse, mutect2, varscan2
- SLC22A2 | c.382T>A p.Y128N | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100871021; called by muse, mutect2, varscan2
- SLC24A1 | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56054024, COSV99978533; called by muse, mutect2, varscan2
- SLC39A10 | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 53/122 reads (43%) | catalogued as COSV62769521; called by muse, mutect2, varscan2
- SLC7A13 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs748074011, COSV52533423; called by muse, mutect2, varscan2
- SLC7A8 | c.1148A>G p.D383G | Missense Mutation (SNP) | VAF 230/445 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV57556181; called by muse, mutect2
- SLC9A5 | c.2395G>T p.E799* | Nonsense Mutation (SNP) | VAF 92/204 reads (45%) | catalogued as COSV55364862; called by muse, mutect2, varscan2
- SLCO4C1 | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs769679748, COSV60520174; called by muse, mutect2, varscan2
- SLIT3 | c.4093G>A p.D1365N | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs770091737, COSV60594584; called by muse, mutect2
- SMC1B | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 51/58 reads (88%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV100663425; called by muse, mutect2, varscan2
- SOS1 | c.1322G>T p.C441F | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM070286, COSV67677222, COSV67677636; called by muse, mutect2, varscan2
- SOX17 | c.464T>C p.F155S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs761510423, COSV52027941; called by muse, mutect2, varscan2
- SP140 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59454902; called by muse, mutect2, varscan2
- SP140 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 57/62 reads (92%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59454910; called by muse, mutect2, varscan2
- SPAG16 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59070187; called by muse, mutect2, varscan2
- SPAG16 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs763958959, COSV59115239; called by muse, mutect2, varscan2
- SPATA31E1 | c.3610G>A p.G1204S | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as rs1246611593, COSV57795126; called by muse, mutect2, varscan2
- SPHKAP | c.4256G>A p.R1419Q | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs2396519, COSV60893682; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 46/51 reads (90%) | PolyPhen probably damaging (0.909); catalogued as rs770661319, COSV59130673; called by muse, mutect2, varscan2
- STARD13 | c.941C>T p.S314L (on ENST00000336934 / NM_001243476.3; = p.S196L on NM_052851.3) | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs756440686, COSV55229335; called by muse, mutect2, varscan2
- STAT1 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63117459; called by muse, mutect2, varscan2
- STRIP2 | c.1475T>C p.L492S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.812); catalogued as COSV50803208, COSV50808245; called by muse, mutect2, varscan2
- STYXL1 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 170/460 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV50392589; called by muse, mutect2, varscan2
- SYNGR2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 114/236 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV56746682; called by muse, mutect2, varscan2
- SYNPO2 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as rs759797608, COSV61116874; called by muse, mutect2, varscan2
- SYT1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV54053211; called by muse, mutect2, varscan2
- SYT10 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as COSV57338332, COSV57345417; called by muse, mutect2, varscan2
- TARBP1 | c.2950C>T p.Q984* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV50206060; called by muse, mutect2, varscan2
- TCAF1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.268); catalogued as COSV100584689; called by mutect2, varscan2
- TEKT4 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99726621; called by muse, mutect2
- TENM4 | c.3304T>C p.F1102L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV53669281; called by muse, mutect2, varscan2
- TENM4 | c.3177G>A p.M1059I | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53669304; called by muse, mutect2, varscan2
- TF | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs201067725; called by muse, mutect2
- TFE3 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59949250; called by muse, mutect2, varscan2
- TFEB | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as rs1294083758, COSV57826851; called by muse, mutect2, varscan2
- THADA | c.5147A>G p.N1716S | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV57693058; called by muse, mutect2, varscan2
- THBS2 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100827692, COSV64682160; called by muse, mutect2, varscan2
- THPO | c.670A>C p.I224L (on ENST00000649095 / NM_001290003.1; = p.I84L on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as COSV52617339; called by muse, mutect2, varscan2
- THSD7B | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs781503094, COSV55706486; called by muse, mutect2, varscan2
- TINAG | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1365790052, COSV52510550; called by muse, mutect2, varscan2
- TLR3 | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.464); catalogued as rs774735663, COSV57167543; called by muse, mutect2, varscan2
- TLR4 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV62924204; called by muse, mutect2, varscan2
- TLR4 | c.157C>T p.P53S (on ENST00000355622 / NM_138554.5; = p.P13S on NM_003266.4) | Missense Mutation (SNP) | VAF 60/71 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62924205; called by muse, mutect2, varscan2
- TMEM104 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs112926186, COSV59112151; called by muse, mutect2, varscan2
- TMEM156 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV60745680; called by muse, mutect2, varscan2
- TMEM200A | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV51650522; called by muse, mutect2, varscan2
- TMEM215 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 51/52 reads (98%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.269); catalogued as COSV61364133; called by muse, mutect2, varscan2
- TMPRSS7 | c.1799C>T p.S600F (on ENST00000452346; = p.S474F on NM_001042575.2) | Missense Mutation (SNP) | VAF 118/247 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.062); catalogued as COSV69979623; called by muse, mutect2, varscan2
- TNKS | c.3073G>T p.A1025S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV60066147; called by muse, mutect2, varscan2
- TNP2 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57130093; called by muse, mutect2, varscan2
- TP53BP2 | c.2056C>T p.P686S (on ENST00000343537 / NM_001031685.3; = p.P557S on NM_005426.2) | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1174741876, COSV59072864; called by muse, mutect2, varscan2
- TP53BP2 | c.971C>T p.A324V (on ENST00000343537 / NM_001031685.3; = p.A195V on NM_005426.2) | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100636595, COSV59072878; called by muse, mutect2, varscan2
- TPM1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 117/284 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs769069020, COSV51266647; called by muse, mutect2, varscan2
- TRAPPC11 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 23/38 reads (61%) | catalogued as rs1013356944, COSV58219200; called by muse, mutect2, varscan2
- TRAV8-6 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs539466365; called by muse, mutect2, varscan2
- TREX2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 539/572 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1364630996, COSV100444260; called by muse, mutect2, varscan2
- TREX2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 539/572 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV100444261; called by muse, mutect2, varscan2
- TRIM46 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 286/455 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV55280273; called by muse, mutect2, varscan2
- TRIM48 | c.509A>T p.N170I | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as COSV70163269; called by muse, mutect2, varscan2
- TRIM58 | c.517-1G>A p.X173_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as COSV63569630; called by muse, mutect2, varscan2
- TRIM69 | c.937G>A p.E313K (on ENST00000329464 / NM_182985.5; = p.E154K on NM_080745.5) | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV57805320; called by muse, mutect2, varscan2
- TRUB1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1162061870, COSV53931170; called by muse, mutect2, varscan2
- TSPOAP1 | c.4324C>T p.R1442* | Nonsense Mutation (SNP) | VAF 71/153 reads (46%) | catalogued as rs371656253, COSV52117523; called by muse, mutect2, varscan2
- TTC3 | c.2722C>T p.Q908* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV61296112; called by muse, mutect2, varscan2
- TTLL13P | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV100296697; called by muse, mutect2, varscan2
- TTN | c.21037G>A p.E7013K (on ENST00000591111; = p.E6086K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | PolyPhen benign (0.001); catalogued as COSV60340371; called by muse, mutect2, varscan2
- TULP1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57693849; called by muse, mutect2, varscan2
- TUT4 | c.3868C>T p.P1290S | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57119713; called by muse, mutect2, varscan2
- U2SURP | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV67533204; called by muse, mutect2, varscan2
- ULK4 | c.643+1G>A p.X215_splice | Splice Site (SNP) | VAF 87/227 reads (38%) | catalogued as COSV57223123; called by muse, mutect2, varscan2
- UNC13C | c.4871G>A p.G1624E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267604265, COSV52845412; called by muse, mutect2, varscan2
- USH2A | c.14099C>T p.S4700F | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV56433997; called by muse, mutect2, varscan2
- USH2A | c.7442G>A p.G2481E | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs140341466; called by muse, mutect2, varscan2
- USP31 | c.2898G>C p.Q966H | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV54857062; called by muse, mutect2, varscan2
- USP6 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.117); catalogued as COSV51496077; called by muse, mutect2, varscan2
- VIP | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV65888486; called by muse, mutect2, varscan2
- VPREB1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as COSV56426453; called by muse, mutect2, varscan2
- VRTN | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs754846456, COSV56440828; called by muse, mutect2, varscan2
- VWA2 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 133/288 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs527324502, COSV53911111; called by muse, mutect2, varscan2
- VWC2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV61487545; called by muse, mutect2, varscan2
- WBP1 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 63/148 reads (43%) | catalogued as COSV51968844, COSV51971674; called by muse, mutect2, varscan2
- WDFY2 | c.1166T>G p.V389G | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV53292937; called by muse, mutect2, varscan2
- WDR72 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 55/117 reads (47%) | catalogued as COSV100855056, COSV64753847; called by muse, mutect2, varscan2
- WNT9B | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1229600520, COSV51520037; called by muse, mutect2, varscan2
- WT1 | c.1387+1G>A p.X463_splice | Splice Site (SNP) | VAF 178/396 reads (45%) | catalogued as COSV60083343; called by muse, mutect2, varscan2
- WTIP | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs1345939821, COSV54330494; called by muse, mutect2, varscan2
- XIRP2 | c.5834C>T p.T1945I (on ENST00000628543; = p.T2120I on NM_152381.6) | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV54733226, COSV99747298; called by muse, mutect2, varscan2
- XIRP2 | c.6790G>A p.D2264N (on ENST00000628543; = p.D2439N on NM_152381.6) | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs563915541, COSV54679859; called by muse, mutect2, varscan2
- ZFHX4 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV50813384, COSV99269416; called by muse, mutect2, varscan2
- ZNF121 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.083); catalogued as COSV57551877, COSV57552419; called by muse, mutect2, varscan2
- ZNF142 | c.4046C>T p.A1349V (on ENST00000411696 / NM_001379660.1; = p.A1149V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs150124453, COSV101376982; called by muse, mutect2, varscan2
- ZNF19 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as rs1387926478, COSV55508987; called by muse, mutect2, varscan2
- ZNF423 | c.1697C>T p.S566F (on ENST00000563137 / NM_001379286.1; = p.S558F on NM_015069.4) | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99279570; called by muse, mutect2, varscan2
- ZNF440 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1343344092, COSV58372460; called by muse, mutect2, varscan2
- ZNF496 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs1193223881, COSV54182039; called by muse, mutect2, varscan2
- ZNF608 | c.4258C>T p.Q1420* | Nonsense Mutation (SNP) | VAF 30/31 reads (97%) | catalogued as COSV100102277; called by muse, mutect2, varscan2
- ZNF705A | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV100828345; called by muse, mutect2, varscan2
- ZNF705A | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV100828346; called by muse, mutect2, varscan2
- ZNF787 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs780933938, COSV54420329; called by muse, varscan2
- ZNF823 | c.958C>T p.R320* (on ENST00000341191 / NM_001297610.2; = p.R276* on NM_017507.2) | Nonsense Mutation (SNP) | VAF 54/103 reads (52%) | catalogued as rs759765537, COSV57876245; called by muse, mutect2, varscan2
- ZNF99 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV68056717; called by muse, mutect2, varscan2
- ZNF99 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV101233914; called by muse, mutect2, varscan2
- ZNF99 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV101233915; called by muse, mutect2, varscan2
- ZSWIM2 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54577938; called by muse, mutect2, varscan2
- AATF | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ELOA3B | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PDCD11 | c.3832del p.Q1278Rfs*16 | Frame Shift Del (DEL) | VAF 35/91 reads (38%) | called by mutect2, pindel, varscan2
- PKN1 | c.2264_2266del p.K755del | In Frame Del (DEL) | VAF 96/254 reads (38%) | called by pindel, varscan2
- PRAMEF18 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 61/339 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PRAMEF19 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 109/931 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PTPRZ1 | c.435_438del p.E145Dfs*31 | Frame Shift Del (DEL) | VAF 41/109 reads (38%) | called by mutect2, pindel, varscan2
- TPTE | c.1521-2A>T p.X507_splice (on ENST00000618007 / NM_199261.4; = p.X489_splice on NM_199259.4) | Splice Site (SNP) | VAF 14/31 reads (45%) | called by muse, varscan2
- TRRAP | c.8274_8276del p.E2758del (on ENST00000359863 / NM_001244580.1; = p.E2740del on NM_003496.3) | In Frame Del (DEL) | VAF 40/115 reads (35%) | called by mutect2, pindel, varscan2
- ZBTB21 | c.1746del p.R583Gfs*18 | Frame Shift Del (DEL) | VAF 77/188 reads (41%) | called by mutect2, pindel, varscan2
- A2M | c.306C>T p.F102= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV59392346; called by muse, mutect2, varscan2
- ABHD16A | c.1221C>T p.L407= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV65452577; called by muse, mutect2, varscan2
- ACLY | c.3012C>T p.L1004= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as rs1266370148, COSV59863096; called by muse, mutect2, varscan2
- ADAM23 | c.2169G>A p.R723= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as COSV52229653; called by muse, mutect2, varscan2
- ADAMTS20 | c.4587C>T p.D1529= | Silent (SNP) | VAF 62/142 reads (44%) | catalogued as COSV67139106; called by muse, mutect2, varscan2
- ADGRE1 | c.2532C>T p.H844= | Silent (SNP) | VAF 66/145 reads (46%) | catalogued as COSV51680880; called by muse, mutect2, varscan2
- ADGRG2 | c.972G>A p.T324= (on ENST00000379869 / NM_001079858.3; = p.T321= on NM_005756.4) | Silent (SNP) | VAF 166/176 reads (94%) | catalogued as rs746381297, COSV61338567; called by muse, mutect2, varscan2
- ADGRV1 | c.1398A>G p.T466= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as COSV67995134; called by muse, mutect2, varscan2
- ALB | c.1218A>G p.E406= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV55742476; called by muse, mutect2, varscan2
- ALDOB | c.240C>T p.F80= | Silent (SNP) | VAF 148/164 reads (90%) | catalogued as COSV66398635; called by muse, mutect2, varscan2
- ANK1 | c.1666C>T p.L556= | Silent (SNP) | VAF 59/155 reads (38%) | catalogued as COSV55895539; called by muse, mutect2, varscan2
- ARFGEF2 | c.813C>T p.P271= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV64215048; called by muse, mutect2, varscan2
- ARHGEF10 | c.1776G>A p.Q592= (on ENST00000398564; = p.Q567= on NM_014629.4) | Silent (SNP) | VAF 112/243 reads (46%) | catalogued as rs1446845531, COSV50677198; called by muse, mutect2, varscan2
- ARL14EP | c.540C>T p.T180= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs966044626, COSV56343988, COSV99955992; called by muse, mutect2, varscan2
- ARNTL2 | c.933C>T p.F311= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV53828879; called by muse, mutect2, varscan2
- ARPP21 | c.978G>A p.K326= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as COSV51800779, COSV99492890; called by muse, mutect2, varscan2
- ASH1L | c.8247C>T p.I2749= (on ENST00000368346 / NM_001366177.2; = p.I2744= on NM_018489.3) | Silent (SNP) | VAF 98/170 reads (58%) | catalogued as COSV64213633; called by muse, mutect2, varscan2
- ASL | c.696C>T p.A232= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV59189450; called by muse, mutect2, varscan2
- ATP6V0A4 | c.927G>A p.L309= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV59480244; called by muse, mutect2, varscan2
- BACH2 | c.1590G>A p.E530= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as COSV57608499; called by muse, mutect2, varscan2
- BAIAP2 | c.207C>T p.S69= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs1458303761, COSV58340527; called by muse, mutect2, varscan2
- BFAR | c.438C>T p.S146= | Silent (SNP) | VAF 95/211 reads (45%) | catalogued as rs998887516, COSV99902392; called by muse, mutect2, varscan2
- BMPER | c.819C>T p.S273= | Silent (SNP) | VAF 65/143 reads (45%) | catalogued as COSV51831150; called by muse, mutect2, varscan2
- C1orf159 | c.924C>T p.P308= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV53883600; called by muse, mutect2, varscan2
- CACNA2D3 | c.450G>A p.K150= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV55580960; called by muse, mutect2, varscan2
- CAMK4 | c.567T>C p.S189= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV56682726; called by muse, mutect2
- CCDC172 | c.150C>T p.I50= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV60940350; called by muse, mutect2, varscan2
- CCDC33 | c.1683C>T p.I561= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as rs371292759; called by muse, mutect2, varscan2
- CCDC73 | c.1455C>T p.S485= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs779363003, COSV58804666; called by muse, mutect2, varscan2
- CDC42BPA | c.3468G>A p.R1156= (on ENST00000334218 / NM_001366019.2; = p.R1143= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs1340686041, COSV62021445; called by muse, mutect2, varscan2
- CDH15 | c.285C>T p.F95= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV57027669; called by muse, mutect2, varscan2
- CEACAM18 | c.777C>T p.S259= | Silent (SNP) | VAF 134/270 reads (50%) | catalogued as rs375335639; called by muse, varscan2
- CEACAM8 | c.516G>A p.Q172= | Silent (SNP) | VAF 189/388 reads (49%) | catalogued as rs1433143209, COSV54991761; called by muse, mutect2, varscan2
- CELSR3 | c.8697C>T p.S2899= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs752147044, COSV51148592; called by muse, mutect2, varscan2
- CFHR1 | c.747A>C p.I249= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as COSV57629135; called by muse, mutect2, varscan2
- CFHR5 | c.276G>A p.V92= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV56828240; called by muse, mutect2, varscan2
- CHD5 | c.1878C>T p.I626= | Silent (SNP) | VAF 116/147 reads (79%) | catalogued as rs777063752, COSV52412532; called by muse, mutect2, varscan2
- CHRM2 | c.348C>T p.I116= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as COSV57784326; called by muse, mutect2, varscan2
- CHRNE | c.300C>T p.V100= | Silent (SNP) | VAF 103/231 reads (45%) | catalogued as COSV53420095; called by muse, mutect2, varscan2
- CHST1 | c.69C>T p.I23= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as rs1342761639, COSV57325707; called by muse, mutect2, varscan2
- CMBL | c.684C>T p.P228= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV56983597; called by muse, mutect2, varscan2
- COL1A1 | c.2808C>T p.S936= | Silent (SNP) | VAF 85/166 reads (51%) | catalogued as COSV56809353; called by muse, mutect2, varscan2
- COL6A6 | c.5508C>T p.S1836= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs752394971, COSV62037047; called by muse, mutect2, varscan2
- COL8A2 | c.651G>A p.G217= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs766931276, COSV57442821; called by muse, mutect2, varscan2
- CPAMD8 | c.243G>A p.L81= (on ENST00000651564; = p.L34= on NM_015692.5) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV52239706; called by muse, mutect2, varscan2
- CSRP1 | c.531C>T p.P177= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV100384496; called by muse, mutect2, varscan2
- CTPS2 | c.567C>T p.T189= | Silent (SNP) | VAF 49/52 reads (94%) | catalogued as rs764694933, COSV100826992; called by muse, mutect2, varscan2
- CYP11B1 | c.345C>T p.P115= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV52830222, COSV52830349; called by muse, mutect2, varscan2
- CYP26C1 | c.1320C>T p.S440= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV53653853; called by muse, mutect2, varscan2
- DCN | c.699C>T p.I233= | Silent (SNP) | VAF 96/101 reads (95%) | catalogued as COSV50009239; called by muse, mutect2, varscan2
- DDN | c.1467C>T p.S489= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV60294761; called by muse, mutect2, varscan2
- DNAH3 | c.4155C>T p.I1385= | Silent (SNP) | VAF 88/215 reads (41%) | catalogued as COSV54550674; called by muse, mutect2, varscan2
- DNAH5 | c.7746G>A p.Q2582= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs1396143112, COSV54213038, COSV54244996; ClinVar: likely benign; called by muse, mutect2, varscan2
- DSG4 | c.954C>T p.F318= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs764648086, COSV57388649; called by muse, mutect2, varscan2
- DYSF | c.1158C>T p.F386= | Silent (SNP) | VAF 132/302 reads (44%) | catalogued as COSV50279805; called by muse, mutect2
- EGR2 | c.675C>T p.D225= | Silent (SNP) | VAF 93/189 reads (49%) | catalogued as COSV54348874; called by muse, mutect2, varscan2
- ELAPOR2 | c.2341C>T p.L781= (on ENST00000450689 / NM_001142749.3; = p.L614= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as COSV51891725, COSV51893264; called by muse, mutect2, varscan2
- ENAM | c.900G>A p.Q300= | Silent (SNP) | VAF 55/139 reads (40%) | catalogued as COSV68536995; called by muse, mutect2, varscan2
- ENPEP | c.2455C>T p.L819= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV54457287; called by muse, mutect2, varscan2
- EPB41L4A | c.108G>A p.T36= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs750688199, COSV54863080, COSV54879195; called by muse, mutect2, varscan2
- EPHB4 | c.2664C>T p.A888= | Silent (SNP) | VAF 81/170 reads (48%) | catalogued as COSV100639606; called by muse, mutect2, varscan2
- ERICH6 | c.1047G>A p.Q349= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as COSV55803223; called by muse, mutect2, varscan2
- ERN2 | c.2562G>A p.R854= | Silent (SNP) | VAF 139/339 reads (41%) | catalogued as COSV55624253; called by muse, mutect2, varscan2
- ERN2 | c.1797G>A p.Q599= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as COSV55624257; called by muse, mutect2, varscan2
- FAM193A | c.2241C>T p.H747= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV61198631; called by muse, mutect2, varscan2
- FAM209B | c.57C>T p.A19= | Silent (SNP) | VAF 109/246 reads (44%) | catalogued as rs757807373, COSV64915684; called by muse, mutect2, varscan2
- FCGBP | c.11577C>T p.F3859= | Silent (SNP) | VAF 122/267 reads (46%) | catalogued as rs772618686; called by muse, mutect2, varscan2
- FCRL3 | c.822G>A p.L274= | Silent (SNP) | VAF 64/143 reads (45%) | catalogued as rs1467866444, COSV63844835; called by muse, mutect2, varscan2
- FLG | c.226C>T p.L76= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV64248876; called by muse, mutect2, varscan2
- FRMPD3 | c.1881C>T p.A627= | Silent (SNP) | VAF 44/50 reads (88%) | catalogued as COSV99346860; called by muse, mutect2, varscan2
- FSHR | c.1683C>T p.I561= | Silent (SNP) | VAF 47/87 reads (54%) | catalogued as rs757713421, COSV58623930; called by muse, mutect2, varscan2
- GABBR1 | c.1488G>A p.E496= | Silent (SNP) | VAF 86/189 reads (46%) | catalogued as COSV63544494; called by muse, mutect2, varscan2
- GCNT1 | c.90C>T p.S30= | Silent (SNP) | VAF 39/43 reads (91%) | catalogued as rs1385202805, COSV65058808; called by muse, mutect2, varscan2
- GIMAP4 | c.903G>A p.V301= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as COSV55434590; called by muse, mutect2, varscan2
- GOLPH3L | c.720C>T p.S240= | Silent (SNP) | VAF 144/237 reads (61%) | catalogued as COSV55047824; called by muse, mutect2, varscan2
- GPR139 | c.672G>A p.G224= | Silent (SNP) | VAF 89/209 reads (43%) | catalogued as rs1372860501, COSV58502817; called by muse, mutect2, varscan2
- GRIN3A | c.1914G>A p.R638= | Silent (SNP) | VAF 69/72 reads (96%) | catalogued as rs752073776, COSV100701428, COSV62458071; called by muse, mutect2, varscan2
- GSTM5 | c.93G>A p.K31= | Silent (SNP) | VAF 90/185 reads (49%) | catalogued as rs1158434732, COSV56660261; called by muse, mutect2, varscan2
- HERC1 | c.9654C>T p.I3218= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV101496803; called by muse, mutect2, varscan2
- HFM1 | c.1536C>T p.T512= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as rs775555716, COSV54023245; called by muse, mutect2, varscan2
- HGSNAT | c.1092C>T p.L364= | Silent (SNP) | VAF 264/567 reads (47%) | catalogued as COSV52819055; called by muse, mutect2, varscan2
- HP1BP3 | c.1530A>G p.R510= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV56564655; called by muse, mutect2, varscan2
- HYLS1 | c.423G>A p.Q141= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as COSV54992711; called by muse, mutect2, varscan2
- IGSF10 | c.3540A>G p.S1180= | Silent (SNP) | VAF 118/261 reads (45%) | catalogued as COSV56791495; called by muse, mutect2, varscan2
- IGSF21 | c.582C>T p.P194= | Silent (SNP) | VAF 61/141 reads (43%) | catalogued as COSV52144201; called by muse, mutect2, varscan2
- ILVBL | c.189G>A p.R63= | Silent (SNP) | VAF 58/178 reads (33%) | catalogued as COSV99655072; called by muse, mutect2, varscan2
- JADE1 | c.1065G>A p.E355= | Silent (SNP) | VAF 133/289 reads (46%) | catalogued as COSV56909247; called by muse, mutect2, varscan2
- KCNK1 | c.126C>T p.S42= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV64040045; called by muse, mutect2, varscan2
- KCNK9 | c.327C>T p.F109= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV57288267; called by muse, mutect2, varscan2
- KLC4 | c.1780C>T p.L594= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as COSV52439186; called by muse, mutect2, varscan2
- KMT2D | c.1611C>T p.S537= | Silent (SNP) | VAF 92/206 reads (45%) | catalogued as COSV56485189; called by muse, mutect2, varscan2
- LHFPL5 | c.357C>T p.F119= | Silent (SNP) | VAF 82/139 reads (59%) | catalogued as COSV64178720; called by muse, mutect2, varscan2
- LILRA1 | c.846C>T p.F282= | Silent (SNP) | VAF 100/269 reads (37%) | catalogued as rs770991679, COSV52184837; called by muse, varscan2
- LIMS1 | c.477C>T p.F159= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2
- LNX1 | c.1752G>C p.S584= (on ENST00000263925 / NM_001126328.3; = p.S488= on NM_032622.2) | Silent (SNP) | VAF 117/240 reads (49%) | catalogued as rs752968070, COSV55782234, COSV99819947; called by muse, mutect2, varscan2
- LRRCC1 | c.1929C>T p.F643= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV64485733; called by muse, mutect2, varscan2
- LRTM1 | c.672C>T p.I224= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV55510045; called by muse, mutect2, varscan2
- LYPD1 | c.237C>T p.I79= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1229206607, COSV61416148, COSV61417567; called by muse, mutect2, varscan2
- MC2R | c.186C>T p.F62= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV59618167; called by muse, mutect2, varscan2
- MCTP1 | c.1851G>A p.R617= | Silent (SNP) | VAF 48/91 reads (53%) | catalogued as COSV56524207, COSV56529801; called by muse, mutect2, varscan2
- MERTK | c.1440C>T p.I480= | Silent (SNP) | VAF 101/224 reads (45%) | catalogued as COSV54935638; called by muse, mutect2, varscan2
- MKI67 | c.396C>T p.D132= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV64076877; called by muse, mutect2, varscan2
- MUC16 | c.9624C>T p.I3208= | Silent (SNP) | VAF 82/191 reads (43%) | catalogued as rs867843483, COSV67492507; called by muse, mutect2, varscan2
- MYL1 | c.318G>A p.K106= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV100498791, COSV58976822; called by muse, mutect2, varscan2
- MYO3B | c.2103A>C p.T701= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV58717318; called by muse, mutect2, varscan2
- MYT1L | c.3213G>A p.K1071= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as COSV67704859; called by muse, mutect2, varscan2
- NALCN | c.1359C>T p.F453= | Silent (SNP) | VAF 62/133 reads (47%) | catalogued as rs769221073, COSV51932226; called by muse, mutect2, varscan2
- NAP1L4 | c.708C>T p.P236= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV65882206; called by muse, mutect2, varscan2
- NLRC5 | c.1359C>T p.P453= | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as COSV52663015; called by muse, mutect2, varscan2
- NLRC5 | c.3021C>T p.L1007= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV99347986; called by muse, mutect2, varscan2
- NLRP3 | c.864C>T p.I288= | Silent (SNP) | VAF 83/269 reads (31%) | catalogued as rs200900704, COSV60221686; called by muse, mutect2, varscan2
- NOS1 | c.468G>A p.G156= | Silent (SNP) | VAF 147/153 reads (96%) | catalogued as rs753350227, COSV57609091; called by muse, mutect2, varscan2
- NPFFR2 | c.1173C>T p.P391= | Silent (SNP) | VAF 57/116 reads (49%) | catalogued as rs774565779, COSV58154298; called by muse, mutect2, varscan2
- NRAP | c.621G>A p.V207= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs1157202473, COSV63493860; called by muse, mutect2, varscan2
- OR10AG1 | c.780G>A p.R260= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100400152, COSV56634119, COSV56634644; called by muse, varscan2
- OR10K1 | c.631C>T p.L211= | Silent (SNP) | VAF 160/259 reads (62%) | catalogued as rs149900631; called by muse, mutect2, varscan2
- OR11H12 | c.678C>T p.F226= | Silent (SNP) | VAF 50/178 reads (28%) | catalogued as COSV101612518; called by mutect2, varscan2
- OR13C5 | c.153G>A p.L51= | Silent (SNP) | VAF 54/76 reads (71%) | catalogued as COSV101053017; called by muse, mutect2, varscan2
- OR14K1 | c.228C>T p.V76= | Silent (SNP) | VAF 49/161 reads (30%) | catalogued as COSV51722351; called by muse, mutect2, varscan2
- OR2A25 | c.201C>T p.V67= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs1373800481, COSV68717536; called by muse, mutect2
- OR2L3 | c.180C>T p.F60= | Silent (SNP) | VAF 193/685 reads (28%) | catalogued as COSV63454535; called by muse, mutect2, varscan2
- OR4A15 | c.817C>T p.L273= | Silent (SNP) | VAF 75/171 reads (44%) | catalogued as COSV59036414, COSV59037594; called by muse, mutect2, varscan2
- OR4N5 | c.129C>T p.F43= | Silent (SNP) | VAF 148/290 reads (51%) | catalogued as COSV61321332; called by muse, mutect2, varscan2
- OR4N5 | c.678G>A p.R226= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as COSV61320958; called by muse, mutect2, varscan2
- OR52K2 | c.903C>T p.I301= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs1183045273, COSV57834631; called by muse, mutect2, varscan2
- OR5L1 | c.186C>T p.F62= | Silent (SNP) | VAF 157/323 reads (49%) | catalogued as rs267602977, COSV100450200, COSV61733899; called by muse, mutect2, varscan2
- OR5M11 | c.912G>A p.L304= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV73142006; called by muse, mutect2, varscan2
- OR6C2 | c.585G>A p.Q195= | Silent (SNP) | VAF 80/156 reads (51%) | catalogued as COSV59516929; called by muse, mutect2, varscan2
- OR8B2 | c.660C>T p.F220= | Silent (SNP) | VAF 75/159 reads (47%) | catalogued as COSV66665200; called by muse, mutect2, varscan2
- OR8B8 | c.378C>T p.I126= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV60145272, COSV60145719; called by muse, mutect2
- OR8G2P | c.186C>T p.F62= | Silent (SNP) | VAF 122/237 reads (51%) | catalogued as rs768153434; called by muse, varscan2
- OR9Q2 | c.402C>T p.T134= | Silent (SNP) | VAF 100/187 reads (53%) | catalogued as COSV61112722; called by muse, mutect2, varscan2
- PCDHA9 | c.2112C>T p.I704= | Silent (SNP) | VAF 94/105 reads (90%) | catalogued as COSV65325426, COSV65332501; called by muse, mutect2, varscan2
- PCDHB1 | c.78G>A p.G26= | Silent (SNP) | VAF 42/47 reads (89%) | catalogued as COSV60633237; called by muse, mutect2, varscan2
- PCGF3 | c.591C>T p.S197= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as rs947859226, COSV100744908, COSV62860638; called by muse, mutect2, varscan2
- PDE6B | c.570C>T p.I190= | Silent (SNP) | VAF 72/165 reads (44%) | catalogued as COSV55330801; called by muse, mutect2, varscan2
- PDIA5 | c.681C>T p.F227= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV60248453; called by muse, mutect2, varscan2
- PDS5B | c.3882A>C p.P1294= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as COSV59734399; called by muse, mutect2, varscan2
- PDSS2 | c.1125C>T p.A375= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV64657919; called by muse, mutect2, varscan2
- PDZD2 | c.4558C>T p.L1520= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs757933877, COSV56872307; called by muse, mutect2, varscan2
- PITPNM3 | c.2280C>T p.V760= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV52599952; called by muse, mutect2, varscan2
- PLCXD3 | c.519G>A p.A173= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as rs377065100, COSV60605164; called by muse, mutect2, varscan2
- PLCZ1 | c.915G>A p.K305= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV56858575; called by muse, mutect2, varscan2
- PLXNB1 | c.4152C>T p.N1384= | Silent (SNP) | VAF 108/231 reads (47%) | catalogued as COSV56494102; called by muse, mutect2, varscan2
- POR | c.60C>T p.A20= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs782030124, COSV101203719; called by muse, mutect2, varscan2
- PPP6R2 | c.828G>A p.L276= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV99324671; called by muse, mutect2, varscan2
- PRDM4 | c.90A>C p.S30= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV57307606; called by muse, mutect2, varscan2
- PSMD2 | c.144G>A p.E48= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV59531403; called by muse, mutect2, varscan2
- PTHLH | c.267G>A p.K89= | Silent (SNP) | VAF 121/284 reads (43%) | catalogued as rs866890264, COSV52369434; called by muse, mutect2, varscan2
- PTPRE | c.1314C>T p.I438= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs1176474209, COSV54558612; called by muse, mutect2, varscan2
- RABEP1 | c.2493G>A p.Q831= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV52588355; called by muse, mutect2, varscan2
- RELN | c.237A>T p.S79= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV59033059; called by muse, mutect2, varscan2
- RGS7 | c.1041C>T p.F347= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV58542722; called by muse, mutect2, varscan2
- RIPPLY1 | c.345G>A p.G115= | Silent (SNP) | VAF 38/41 reads (93%) | catalogued as rs773181899, COSV52174552; called by muse, mutect2, varscan2
- SALL4 | c.306C>T p.I102= | Silent (SNP) | VAF 102/190 reads (54%) | catalogued as COSV53853400, COSV53855952; called by muse, mutect2, varscan2
- SCARA5 | c.465G>A p.G155= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV57281399; called by muse, mutect2, varscan2
- SCN3B | c.480C>T p.I160= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV54801251; called by muse, mutect2, varscan2
- SGSM2 | c.1995C>T p.P665= (on ENST00000426855 / NM_001098509.2; = p.P710= on NM_014853.3) | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs1375577013, COSV99280415; called by muse, mutect2, varscan2
- SIM1 | c.588G>A p.L196= | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as COSV53496633; called by muse, mutect2, varscan2
- SIN3A | c.1695C>T p.Y565= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV64584970; called by muse, mutect2, varscan2
- SLC12A3 | c.2989C>T p.L997= (on ENST00000563236 / NM_001126108.2; = p.L1006= on NM_000339.3) | Silent (SNP) | VAF 73/154 reads (47%) | catalogued as rs1191004604, COSV52638929; called by muse, mutect2, varscan2
- SLC22A13 | c.294C>T p.I98= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as COSV61292134; called by muse, mutect2, varscan2
- SLC22A2 | c.381G>A p.V127= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV65266215; called by muse, mutect2, varscan2
- SLC25A11 | c.195C>T p.F65= | Silent (SNP) | VAF 67/133 reads (50%) | catalogued as COSV52592063; called by muse, mutect2, varscan2
- SLC3A1 | c.633C>T p.F211= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV53220885; called by muse, mutect2, varscan2
- SMARCAD1 | c.1576C>T p.L526= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV62775479, COSV62776190; called by muse, mutect2, varscan2
- SMC1B | c.2991C>T p.A997= | Silent (SNP) | VAF 50/57 reads (88%) | catalogued as COSV100663424; called by muse, mutect2, varscan2
- SMG7 | c.3396C>T p.T1132= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV61634220; called by muse, mutect2, varscan2
- SOS1 | c.2575C>T p.L859= | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as COSV67677631; called by muse, mutect2, varscan2
- SQLE | c.129C>T p.S43= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV56282615; called by muse, mutect2, varscan2
- SSR2 | c.138C>T p.I46= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as COSV55304978; called by muse, mutect2, varscan2
- ST7 | c.163T>C p.L55= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV55392662; called by muse, mutect2, varscan2
- STAT5B | c.180C>T p.L60= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV53181202, COSV53185856; called by muse, mutect2, varscan2
- SYT10 | c.948C>T p.F316= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV57345424; called by muse, mutect2, varscan2
- TACC2 | c.1092G>A p.K364= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as COSV57772450; called by muse, mutect2, varscan2
- TADA3 | c.591C>T p.S197= | Silent (SNP) | VAF 73/159 reads (46%) | catalogued as COSV57334454; called by muse, mutect2, varscan2
- TECTA | c.4239C>T p.V1413= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV50802734; called by muse, mutect2, varscan2
- TEKT4 | c.309G>A p.S103= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs111669261; called by muse, mutect2
- TET3 | c.4272G>A p.E1424= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs1558796884, COSV69645554; called by muse, mutect2, varscan2
- TEX45 | c.1422C>T p.F474= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs1233999063, COSV64462719; called by muse, mutect2, varscan2
- TNS3 | c.3171G>C p.A1057= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV60799163; called by muse, mutect2, varscan2
- TOGARAM2 | c.288C>T p.A96= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV65423853; called by muse, mutect2, varscan2
- TOR2A | c.531C>T p.F177= | Silent (SNP) | VAF 28/31 reads (90%) | catalogued as COSV59129468; called by muse, mutect2, varscan2
- TPO | c.51A>G p.E17= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV61111093; called by muse, mutect2, varscan2
- TRANK1 | c.7353G>A p.K2451= | Silent (SNP) | VAF 81/182 reads (45%) | catalogued as COSV57163772; called by muse, mutect2, varscan2
- TRANK1 | c.6207C>T p.C2069= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100082211, COSV57163799; called by muse, mutect2, varscan2
- TRERF1 | c.1119C>T p.S373= | Silent (SNP) | VAF 138/293 reads (47%) | catalogued as COSV61677950; called by muse, mutect2, varscan2
- TRPM2 | c.3115C>T p.L1039= | Silent (SNP) | VAF 266/610 reads (44%) | catalogued as COSV55976673; called by muse, mutect2, varscan2
- TTLL13P | c.231G>A p.G77= | Silent (SNP) | VAF 94/223 reads (42%) | catalogued as COSV100296698; called by muse, mutect2, varscan2
- TTN | c.12831G>A p.Q4277= (on ENST00000591111; = p.Q4231= on NM_003319.4) | Silent (SNP) | VAF 53/87 reads (61%) | catalogued as rs188071134, COSV100624646; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- UBR4 | c.9750C>T p.F3250= | Silent (SNP) | VAF 63/161 reads (39%) | catalogued as COSV64399121; called by muse, mutect2, varscan2
- VN1R4 | c.474C>T p.I158= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV60804679; called by muse, mutect2, varscan2
- VN1R5 | c.1038G>A p.L346= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- XKR7 | c.1170C>T p.I390= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs1424869909, COSV73813467; called by muse, mutect2, varscan2
- YEATS2 | c.1026G>A p.Q342= | Silent (SNP) | VAF 74/167 reads (44%) | catalogued as rs1380604799, COSV59372334; called by muse, mutect2, varscan2
- ZFP42 | c.600G>A p.R200= | Silent (SNP) | VAF 86/205 reads (42%) | catalogued as COSV100479200, COSV58819263; called by muse, mutect2, varscan2
- ZFYVE26 | c.759C>T p.P253= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV61333447; called by muse, mutect2, varscan2
- ZNF142 | c.4047C>T p.A1349= (on ENST00000411696 / NM_001379660.1; = p.A1149= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV101376981; called by muse, mutect2, varscan2
- ZNF347 | c.1170C>T p.I390= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV61968470; called by muse, mutect2, varscan2
- ZNF423 | c.1698C>T p.S566= (on ENST00000563137 / NM_001379286.1; = p.S558= on NM_015069.4) | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as COSV99279566; called by muse, mutect2, varscan2
- ZNF521 | c.3387G>T p.G1129= | Silent (SNP) | VAF 58/103 reads (56%) | catalogued as COSV64131815; called by muse, mutect2, varscan2
- ZNF608 | c.4257C>T p.L1419= | Silent (SNP) | VAF 30/31 reads (97%) | catalogued as COSV100102280; called by muse, mutect2, varscan2
- ZNF669 | c.393C>T p.S131= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV58539307; called by muse, mutect2, varscan2
- ZSCAN20 | c.1629C>T p.L543= | Silent (SNP) | VAF 81/169 reads (48%) | catalogued as COSV63684529; called by muse, mutect2, varscan2
- CTSC | c.318+8504G>A | Intron (SNP) | VAF 28/76 reads (37%) | catalogued as COSV99910902; called by muse, mutect2, varscan2
- DCHS2 | n.8300G>A | RNA (SNP) | VAF 36/94 reads (38%) | catalogued as rs572747172, COSV61779347; called by muse, mutect2, varscan2
- DUSP13 | c.*656T>A | 3'UTR (SNP) | VAF 103/219 reads (47%) | catalogued as COSV57816447; called by muse, mutect2, varscan2
- FAM174C | c.*301C>A | 3'UTR (SNP) | VAF 74/175 reads (42%) | catalogued as COSV101331227, COSV69702855; called by muse, mutect2, varscan2
- FAM174C | c.*302C>T | 3'UTR (SNP) | VAF 76/177 reads (43%) | catalogued as COSV101331228; called by muse, mutect2, varscan2
- MAGI1 | c.3635-1971G>A | Intron (SNP) | VAF 125/295 reads (42%) | catalogued as COSV100442624; called by muse, mutect2, varscan2
- OFCC1 | n.393-2951T>G | Intron (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1537C>T | RNA (SNP) | VAF 54/120 reads (45%) | catalogued as rs372664160; called by muse, mutect2, varscan2
- SCD5 | c.569+19730C>T | Intron (SNP) | VAF 143/356 reads (40%) | catalogued as COSV99908194; called by muse, mutect2, varscan2
- SRSF6 | c.257-567C>T | Intron (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2081G>A | Intron (SNP) | VAF 64/144 reads (44%) | catalogued as rs372066215; called by muse, mutect2, varscan2
- TTN | c.34265-5047G>A | Intron (SNP) | VAF 117/296 reads (40%) | catalogued as COSV100624645; called by muse, mutect2, varscan2
- USH1C | c.1284+7659C>T | Intron (SNP) | VAF 37/68 reads (54%) | catalogued as COSV99141181; called by muse, mutect2, varscan2
- XKR6 | c.765-110420T>C | Intron (SNP) | VAF 108/207 reads (52%) | catalogued as COSV101130997; called by muse, mutect2, varscan2
